Somatic mutation profile of tumor specimen MP2PRT-PAVUSC-TMP1-A (aliquot MP2PRT-PAVUSC-TMP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVUSC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,222 days).
Specimen MP2PRT-PAVUSC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 071a0525-bc52-4173-879e-c8ebf1eb93ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUSC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUSC-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/812fd0a8-dd67-4e2a-84c8-602ee4e83f57

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs758085328; called by muse, mutect2, varscan2
- DNAH8 | c.8070C>G p.H2690Q | Missense Mutation (SNP) | VAF 127/299 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs564511128; called by muse, mutect2, varscan2
- FBLN1 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 187/440 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770235111, COSV99410052, COSV99410916; called by muse, mutect2, varscan2
- LAP3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs781426185, COSV56900076, COSV56900147; called by muse, varscan2
- ZFHX4 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs753826139, COSV50923966, COSV51478154; called by muse, mutect2, varscan2
- DRD4 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 399/948 reads (42%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- FREM1 | c.3180G>C p.L1060F | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABBR2 | c.2062G>A p.D688N | Missense Mutation (SNP) | VAF 142/352 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRPPRC | c.2747T>G p.I916S | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PXYLP1 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 153/370 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ZNF208 | c.3593A>G p.K1198R | Missense Mutation (SNP) | VAF 124/284 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- AP1S1 | c.237C>T p.I79= | Silent (SNP) | VAF 20/303 reads (7%) | called by muse, mutect2
- HDX | c.1377C>A p.T459= | Silent (SNP) | VAF 130/164 reads (79%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1779C>T p.A593= | Silent (SNP) | VAF 200/243 reads (82%) | catalogued as rs368495685, COSV100145417; called by muse, mutect2, varscan2
- MEGF8 | c.5670G>T p.G1890= (on ENST00000251268 / NM_001271938.2; = p.G1823= on NM_001410.3) | Silent (SNP) | VAF 222/522 reads (43%) | called by muse, mutect2, varscan2
